Somatic mutation profile of tumor specimen TCGA-CQ-7068-01A (aliquot TCGA-CQ-7068-01A-11D-2078-08) from TCGA case TCGA-CQ-7068, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 80.8 years (29,530 days).
Specimen TCGA-CQ-7068-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ef532580-14b9-4c94-b82e-63e1fb1147a0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CQ-7068-10A (Blood Derived Normal), aliquot TCGA-CQ-7068-10A-01D-2078-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7c609896-69eb-4536-a12b-89bad98581cf

The open-access MAF lists 120 somatic variants for this specimen: 80 protein-altering or splice-affecting, 32 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 71, Silent 32, Nonsense Mutation 4, Frame Shift Del 3, RNA 3, Intron 2, 3'UTR 2, In Frame Ins 1, 5'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HRAS | c.38G>T p.G13V | Missense Mutation (SNP) | VAF 11/26 reads (42%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as rs104894226, CM053285, COSV54237021, COSV54237051; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADCY2 | c.2278G>C p.E760Q | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV100602145, COSV100603543; called by muse, mutect2, varscan2
- ANKRD1 | c.368C>T p.T123M | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0.01); catalogued as rs145387010, CM094353; ClinVar: uncertain significance; called by muse, mutect2
- ARID5B | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.321); catalogued as COSV99689241; called by muse, mutect2, varscan2
- ATP8B4 | c.2409del p.K804Sfs*19 | Frame Shift Del (DEL) | VAF 27/82 reads (33%) | catalogued as COSV52718648; called by mutect2, pindel, varscan2
- AXL | c.207G>A p.W69* | Nonsense Mutation (SNP) | VAF 12/43 reads (28%) | catalogued as COSV56575356; called by muse, mutect2, varscan2
- BCAS1 | c.685G>A p.G229S | Missense Mutation (SNP) | VAF 56/215 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.193); catalogued as COSV101006056; called by muse, mutect2, varscan2
- CADM3 | c.332C>G p.S111* (on ENST00000368125 / NM_001127173.3; = p.S145* on NM_021189.5) | Nonsense Mutation (SNP) | VAF 27/75 reads (36%) | catalogued as COSV100930287; called by muse, mutect2, varscan2
- CASP8 | c.923A>G p.D308G (on ENST00000432109 / NM_033355.3; = p.D325G on NM_001228.4) | Missense Mutation (SNP) | VAF 68/110 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV51852746, COSV99629948; called by muse, mutect2, varscan2
- CCDC180 | c.218G>A p.S73N | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.429); catalogued as COSV100826617; called by muse, mutect2, varscan2
- CEMIP | c.1070G>A p.R357H | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as rs199832741, COSV54992109; called by muse, mutect2, varscan2
- CGNL1 | c.1364C>T p.S455L | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs1182384216, COSV99847750; called by muse, mutect2, varscan2
- CHM | c.20C>T p.S7L | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT deleterious (0.01); PolyPhen benign (0.325); catalogued as rs1357495676, CM137294, COSV62564733; called by muse, mutect2, varscan2
- CHST1 | c.907G>A p.E303K | Missense Mutation (SNP) | VAF 36/60 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100346089; called by muse, mutect2, varscan2
- CTNNA1 | c.1564G>C p.D522H | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100242377; called by muse, mutect2, varscan2
- DHX57 | c.2464G>A p.D822N | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.068); catalogued as COSV99769201; called by muse, mutect2, varscan2
- DMRTC2 | c.245C>T p.A82V | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.966); catalogued as COSV99523334; called by muse, mutect2, varscan2
- DPYS | c.1459C>G p.P487A | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV100679396, COSV100679561; called by muse, mutect2, varscan2
- EPHA3 | c.2405C>G p.T802R | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369423490, COSV100345989; called by muse, mutect2, varscan2
- ESPNL | c.2911C>G p.R971G | Missense Mutation (SNP) | VAF 20/29 reads (69%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs578197417, COSV100547665; called by muse, mutect2, varscan2
- FAM135B | c.338T>C p.V113A | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.334); catalogued as COSV99356459; called by muse, mutect2
- FAM149A | c.1968C>A p.S656R (on ENST00000356371 / NM_001367768.2; = p.S365R on NM_015398.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.797); catalogued as COSV99906426; called by muse, mutect2, varscan2
- GAP43 | c.247G>C p.E83Q | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.583); catalogued as COSV100525388, COSV59348544; called by muse, mutect2, varscan2
- GPBP1 | c.1065G>C p.E355D | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.023); catalogued as COSV53312701, COSV99302569; called by muse, mutect2, varscan2
- GPT2 | c.407G>T p.R136L | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.519); catalogued as COSV100412837, COSV60838656; called by muse, mutect2, varscan2
- GUCD1 | c.254G>T p.C85F | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0.052); catalogued as COSV101238109; called by muse, mutect2, varscan2
- GYPA | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV51618883, COSV51632369; called by muse, mutect2, varscan2
- HBP1 | c.452G>A p.R151H | Missense Mutation (SNP) | VAF 43/112 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs151293151; called by muse, mutect2, varscan2
- HMCN1 | c.275G>T p.G92V | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99625868; called by muse, mutect2, varscan2
- HUWE1 | c.12445G>A p.E4149K | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53342424; called by muse, mutect2, varscan2
- IFT140 | c.24G>T p.Q8H | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.17); catalogued as COSV101276307; called by muse, mutect2, varscan2
- IGSF1 | c.1114G>A p.D372N | Missense Mutation (SNP) | VAF 39/70 reads (56%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as rs751436069, COSV63838194; called by muse, mutect2, varscan2
- ILVBL | c.927G>C p.E309D | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.877); catalogued as COSV99654475, COSV99654662; called by muse, mutect2, varscan2
- IRF6 | c.259C>T p.L87F | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM092332, COSV100883913; called by muse, mutect2, varscan2
- IWS1 | c.814C>T p.R272* | Nonsense Mutation (SNP) | VAF 83/249 reads (33%) | catalogued as COSV54870669; called by muse, mutect2, varscan2
- KIAA1217 | c.5450C>T p.S1817F | Missense Mutation (SNP) | VAF 44/146 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.347); catalogued as COSV100286318; called by muse, mutect2, varscan2
- KRT14 | c.1128G>A p.M376I | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as COSV51422889; called by muse, mutect2, varscan2
- KRT78 | c.829G>C p.D277H | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs745678209, COSV100467184; called by muse, mutect2, varscan2
- LEPR | c.1473G>C p.Q491H | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV100756408; called by muse, mutect2, varscan2
- LSG1 | c.67C>T p.R23W | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as COSV99503092; called by muse, mutect2, varscan2
- MAP4 | c.2636C>T p.A879V | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.49); catalogued as rs1042414808, COSV99274890; called by muse, mutect2, varscan2
- MTUS2 | c.2803G>A p.A935T | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.102); catalogued as rs377003171, COSV54994077; called by muse, mutect2, varscan2
- NOS3 | c.785G>A p.R262Q | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.338); catalogued as rs750247122, COSV52495450; called by muse, mutect2
- NUBP2 | c.247C>T p.R83W | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); catalogued as rs375596127; called by muse, mutect2, varscan2
- ODF3L2 | c.724G>A p.A242T | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as rs371698557, COSV99198940; called by muse, mutect2
- OR10A2 | c.694C>T p.L232F | Missense Mutation (SNP) | VAF 114/161 reads (71%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); catalogued as rs368896870; called by muse, mutect2, varscan2
- OR1D2 | c.574A>G p.I192V | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.086); catalogued as COSV100513884; called by muse, mutect2, varscan2
- OR2T33 | c.146G>T p.W49L | Missense Mutation (SNP) | VAF 28/118 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100531717; called by muse, varscan2
- OR5T1 | c.148A>G p.T50A | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as COSV100478817, COSV57303613; called by muse, mutect2, varscan2
- OR6K2 | c.631G>A p.A211T | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.088); catalogued as rs200416710, COSV100656736; called by muse, mutect2, varscan2
- PC | c.2264T>C p.L755P | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV100546990; called by muse, mutect2, varscan2
- PCDH7 | c.3025C>T p.P1009S | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100687766; called by muse, mutect2, varscan2
- PCLAF | c.167G>A p.R56H | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.882); catalogued as rs1228885660, COSV55539912, COSV55540442; called by muse, mutect2, varscan2
- PIP5K1A | c.339C>G p.F113L (on ENST00000368888 / NM_001135638.2; = p.F100L on NM_003557.3) | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); catalogued as COSV100576551; called by muse, mutect2, varscan2
- PMPCA | c.668G>A p.R223H | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs776990571, COSV65509488; called by muse, mutect2, varscan2
- RGL4 | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.606); catalogued as COSV99318672; called by muse, mutect2, varscan2
- RIMS1 | c.643C>T p.R215* | Nonsense Mutation (SNP) | VAF 14/62 reads (23%) | catalogued as COSV53451570; called by muse, mutect2
- SLIT2 | c.212C>T p.T71M | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.806); catalogued as rs1257940389, COSV56565535; called by muse, mutect2, varscan2
- SPATA31D1 | c.545A>T p.E182V | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.446); catalogued as COSV100782594; called by muse, mutect2, varscan2
- SPNS3 | c.743G>A p.C248Y | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as COSV100336897; called by muse, mutect2, varscan2
- TLL1 | c.814C>G p.Q272E | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV99286589; called by muse, mutect2, varscan2
- TLN1 | c.1180G>A p.G394S | Missense Mutation (SNP) | VAF 13/122 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100147468; called by muse, mutect2
- TNFRSF25 | c.315G>C p.E105D | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.115); catalogued as COSV100556313; called by mutect2, varscan2
- TNKS | c.1321G>A p.E441K | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100126445; called by muse, mutect2, varscan2
- TRIM27 | c.1456C>T p.P486S | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101019249; called by muse, mutect2, varscan2
- TTC21A | c.3163C>T p.R1055C | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs200397655, COSV56188189; called by muse, mutect2, varscan2
- TTN | c.35536G>A p.E11846K (on ENST00000591111; = p.E10919K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/16 reads (31%) | PolyPhen probably damaging (0.987); catalogued as COSV100600558; called by muse, mutect2
- TTN | c.31609G>A p.E10537K (on ENST00000591111; = p.E9610K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/40 reads (33%) | PolyPhen benign (0.359); catalogued as COSV100600560; called by muse, mutect2, varscan2
- TULP2 | c.173G>A p.R58H | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.752); catalogued as COSV54386604; called by muse, mutect2, varscan2
- UBL4B | c.254C>T p.P85L | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.043); catalogued as rs372349264; called by muse, mutect2, varscan2
- UBXN2A | c.610G>A p.E204K | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated (0.62); PolyPhen benign (0.248); catalogued as COSV100464860, COSV58336862; called by muse, mutect2, varscan2
- XIRP2 | c.5391C>A p.N1797K (on ENST00000628543; = p.N1972K on NM_152381.6) | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs1341916739, COSV54740666, COSV99740083; called by muse, mutect2, varscan2
- ZBTB43 | c.1346C>T p.S449F | Missense Mutation (SNP) | VAF 41/183 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV100991312; called by muse, mutect2, varscan2
- ZNF215 | c.1256G>A p.R419H | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs139686178; called by muse, mutect2, varscan2
- ZNF319 | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 49/144 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.054); catalogued as COSV99540040; called by muse, mutect2, varscan2
- ZNF382 | c.1357C>T p.L453F | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.879); catalogued as COSV99497556; called by muse, mutect2, varscan2
- ZNF43 | c.348dup p.D117Rfs*3 | Frame Shift Ins (INS) | VAF 16/61 reads (26%) | catalogued as rs936408529; called by mutect2, varscan2
- GTF2IRD2 | c.264_265insGTA p.V88dup | In Frame Ins (INS) | VAF 6/48 reads (13%) | called by mutect2, pindel
- SLC26A7 | c.839del p.N280Tfs*5 | Frame Shift Del (DEL) | VAF 15/69 reads (22%) | called by mutect2, pindel, varscan2
- ZXDA | c.1659_1660del p.F554Hfs*12 | Frame Shift Del (DEL) | VAF 20/84 reads (24%) | called by pindel, varscan2
- ABCA2 | c.2295C>G p.L765= (on ENST00000614293; = p.L735= on NM_001606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as rs771490932, COSV55808693; called by muse, mutect2
- ADGRB2 | c.1314G>A p.G438= | Silent (SNP) | VAF 19/52 reads (37%) | catalogued as COSV99925837; called by muse, mutect2, varscan2
- AFAP1 | c.1345C>T p.L449= | Silent (SNP) | VAF 24/105 reads (23%) | catalogued as COSV100631259; called by muse, mutect2, varscan2
- APOB | c.6282C>T p.N2094= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as rs753672830, COSV99264403; called by muse, mutect2, varscan2
- ATP12A | c.1308A>G p.L436= | Silent (SNP) | VAF 64/225 reads (28%) | catalogued as rs768749384, COSV99517198; called by muse, mutect2, varscan2
- ATP2B3 | c.1113C>T p.I371= | Silent (SNP) | VAF 13/35 reads (37%) | catalogued as rs1311690336, COSV54842061; called by muse, mutect2, varscan2
- BEND3 | c.1719C>T p.F573= | Silent (SNP) | VAF 31/78 reads (40%) | catalogued as rs370245100, COSV64682257; called by muse, mutect2, varscan2
- BUB1 | c.1005G>A p.L335= | Silent (SNP) | VAF 24/76 reads (32%) | catalogued as COSV100241016, COSV100241140; called by muse, mutect2, varscan2
- CDH11 | c.1308G>A p.E436= | Silent (SNP) | VAF 11/57 reads (19%) | catalogued as COSV51768723, COSV99217582; called by muse, mutect2, varscan2
- CELF3 | c.69G>C p.L23= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as COSV99310116; called by muse, mutect2, varscan2
- CPSF2 | c.2340C>T p.A780= | Silent (SNP) | VAF 4/23 reads (17%) | catalogued as rs1173473178, COSV100102672; called by muse, mutect2
- DNAJB8 | c.651G>A p.S217= | Silent (SNP) | VAF 33/111 reads (30%) | catalogued as COSV100048168; called by muse, mutect2, varscan2
- EXT1 | c.126T>A p.G42= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as COSV100983715; called by muse, mutect2, varscan2
- FAM47C | c.93G>A p.A31= | Silent (SNP) | VAF 13/25 reads (52%) | catalogued as rs868908339, COSV63724809; called by muse, mutect2, varscan2
- FBP1 | c.621T>C p.G207= | Silent (SNP) | VAF 40/88 reads (45%) | catalogued as COSV100941113; called by muse, mutect2, varscan2
- FBXO21 | c.1413G>T p.L471= (on ENST00000330622 / NM_033624.3; = p.L464= on NM_015002.3) | Silent (SNP) | VAF 64/251 reads (25%) | catalogued as COSV100401639, COSV100401915; called by muse, mutect2, varscan2
- IGHV2-26 | c.144C>T p.L48= | Silent (SNP) | VAF 17/47 reads (36%) | called by muse, mutect2, varscan2
- NAA30 | c.51T>G p.P17= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV100035790; called by muse, mutect2
- OR1M1 | c.591C>T p.I197= | Silent (SNP) | VAF 19/80 reads (24%) | catalogued as COSV101447550; called by muse, mutect2, varscan2
- OR51I1 | c.546C>G p.L182= | Silent (SNP) | VAF 18/43 reads (42%) | catalogued as COSV100970885; called by muse, mutect2
- OR6A2 | c.30G>C p.V10= | Silent (SNP) | VAF 14/64 reads (22%) | catalogued as rs765902372, COSV100215639, COSV100215766; called by muse, mutect2, varscan2
- PLEC | c.11607C>T p.F3869= (on ENST00000322810 / NM_201380.4; = p.F3759= on NM_000445.5) | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as rs960681181, COSV100512093; called by muse, mutect2, varscan2
- RBX1 | c.210C>T p.V70= | Silent (SNP) | VAF 11/42 reads (26%) | catalogued as rs142549819; called by muse, mutect2, varscan2
- SHH | c.432C>T p.R144= | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as COSV99793313; called by muse, mutect2, varscan2
- SLC36A2 | c.243C>T p.N81= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as rs375216847; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLITRK1 | c.1974G>A p.A658= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as rs1363203251, COSV65675806; called by muse, mutect2, varscan2
- SLITRK5 | c.2163C>T p.G721= | Silent (SNP) | VAF 18/55 reads (33%) | catalogued as COSV61522979; called by muse, mutect2, varscan2
- SPHK2 | c.1227G>A p.P409= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as rs753083611, COSV55337865; called by muse, mutect2, varscan2
- TRAPPC9 | c.1488G>C p.S496= | Silent (SNP) | VAF 19/91 reads (21%) | catalogued as COSV101226996; called by muse, mutect2, varscan2
- TRERF1 | c.2577G>A p.V859= | Silent (SNP) | VAF 15/54 reads (28%) | catalogued as rs866195107, COSV100550201, COSV61676851; called by muse, mutect2, varscan2
- ZBTB16 | c.843G>T p.G281= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as COSV100251152; called by muse, mutect2, varscan2
- ZNF532 | c.3015G>A p.K1005= | Silent (SNP) | VAF 23/76 reads (30%) | catalogued as rs765276518, COSV100266153, COSV60171764; called by muse, mutect2, varscan2
- GCNT2 | c.925+26626C>G | Intron (SNP) | VAF 17/68 reads (25%) | catalogued as COSV100297096; called by muse, mutect2, varscan2
- LINC00173 | n.770C>T | RNA (SNP) | VAF 21/55 reads (38%) | called by muse, mutect2, varscan2
- MIR509-2 | n.51A>T | RNA (SNP) | VAF 36/98 reads (37%) | called by muse, mutect2, varscan2
- OR10P1 | c.*2G>A | 3'UTR (SNP) | VAF 6/17 reads (35%) | catalogued as COSV100548138; called by muse, mutect2, varscan2
- SLC3A2 | chr11:62855329 del AGAA | 5'Flank (DEL) | VAF 17/56 reads (30%) | catalogued as rs750910376; called by mutect2, pindel, varscan2
- TRIM8 | c.*642C>T | 3'UTR (SNP) | VAF 10/38 reads (26%) | catalogued as COSV100193140; called by muse, mutect2, varscan2
- TTN | c.34265-5677T>C | Intron (SNP) | VAF 40/122 reads (33%) | catalogued as COSV100600559; called by muse, mutect2, varscan2
- ZNF658B | n.2288T>G | RNA (SNP) | VAF 76/160 reads (48%) | called by mutect2, varscan2
